Somatic mutation profile of tumor specimen 0DSMY2 from CCDI case PBCIEH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Clear cell sarcoma of kidney; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.5 years (554 days).
Specimen 0DSMY2: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86d3ee2d-9307-42e8-ab1a-02d46edca7d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSMYF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b5daddd-3b4a-4478-8b09-18ed00324a8a

The open-access MAF lists 6 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MRPL10 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 26/493 reads (5%) | called by muse, mutect2
- ESPL1 | c.6030T>G p.L2010= | Silent (SNP) | VAF 35/463 reads (8%) | called by muse, mutect2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 10/215 reads (5%) | called by muse, mutect2
- ATF7 | c.48+95G>A | Intron (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- CRYZL1 | c.905-80_905-51del | Intron (DEL) | VAF 99/211 reads (47%) | called by mutect2, pindel, varscan2
- DDX18 | c.1066+79A>G | Intron (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
